Somatic mutation profile of tumor specimen 0DZOFM from CCDI case PBCUGZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DZOFM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ed75c2d-b716-4a1e-9908-309f9f67e090.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZOFA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6fc8ce0-6ea7-402d-b08f-151fd68345c1

The open-access MAF lists 21 somatic variants for this specimen: 6 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 6, Intron 6, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSF | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1399909494; called by muse, mutect2
- FAM163B | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1034593997; called by muse, mutect2
- HCN1 | c.1975C>A p.R659S | Missense Mutation (SNP) | VAF 39/591 reads (7%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.024); catalogued as rs745561895, COSV100300999, COSV57533051; called by muse, mutect2
- CFAP46 | c.268A>G p.R90G | Missense Mutation (SNP) | VAF 245/509 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CYP4Z1 | c.122G>T p.R41I | Missense Mutation (SNP) | VAF 312/744 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PHKA2 | c.89C>G p.T30R | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- AHNAK2 | c.9609G>A p.Q3203= | Silent (SNP) | VAF 31/662 reads (5%) | called by muse, mutect2
- CHD5 | c.3813C>T p.D1271= | Silent (SNP) | VAF 225/541 reads (42%) | catalogued as rs201484104, COSV52422737; called by muse, mutect2, varscan2
- DSG2 | c.1149A>G p.K383= | Silent (SNP) | VAF 38/1400 reads (3%) | called by muse, mutect2
- GPRC5C | c.693C>T p.G231= (on ENST00000652232; = p.G186= on NM_018653.4) | Silent (SNP) | VAF 84/457 reads (18%) | catalogued as rs139447995; called by muse, mutect2, varscan2
- MEF2C | c.312C>T p.D104= | Silent (SNP) | VAF 190/968 reads (20%) | catalogued as rs587781034, COSV60925997, COSV60936426; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- MTRF1L | c.639C>T p.R213= | Silent (SNP) | VAF 34/848 reads (4%) | catalogued as rs372750968; called by muse, mutect2
- NBPF10 | c.258G>C p.L86= | Silent (SNP) | VAF 13/302 reads (4%) | catalogued as rs587623393; called by muse, mutect2
- ART4 | c.-97C>T | 5'UTR (SNP) | VAF 14/356 reads (4%) | catalogued as rs951100248, COSV57453890; called by muse, mutect2
- DYNC1LI1 | c.147-94G>T | Intron (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- ODF3L2 | c.128-55C>A | Intron (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- PNRC1 | c.-87A>G | 5'UTR (SNP) | VAF 42/134 reads (31%) | catalogued as COSV100259969, COSV60139455; called by muse, mutect2, varscan2
- REXO1 | c.2231-45T>C | Intron (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- SMARCC2 | c.562+83G>A | Intron (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- SRGAP2 | c.2358-660G>T | Intron (SNP) | VAF 25/736 reads (3%) | called by muse, mutect2
- STRAP | c.775+88T>A | Intron (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
